Gene-level copy-number profile of tumor specimen C3N-06046-02 from CPTAC case C3N-06046, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3N-06046-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Penis; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 594f0408-9908-4405-930b-e9214d2bbb1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06046-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/e473d5e4-46c5-4d8d-90cd-300932664d05

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 372; copy number 1: 1,449; copy number 2: 16,190; copy number 3: 8,274; copy number 4: 24,956; copy number 5: 4,354; copy number 6: 1,813; copy number 7: 689; copy number 8: 393; copy number 9: 232; copy number 10: 60; copy number 11: 7; copy number 12: 43; copy number 13: 31; copy number 15: 13; copy number 16: 13.

Homozygous deletions (total copy number 0; autosomes only): 256 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,940,870–190,092,279, 21 genes: FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr6:73,157,517–73,525,587, 22 genes (within-gene range 0–2): RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1.
- chr6:156,776,020–157,210,779, 1 gene (within-gene range 0–2): ARID1B.
- chr6:156,779,678–157,119,706, 4 genes (within-gene range 0–2): MIR4466, AL355297.1, AL162578.1, AL049820.1.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr8:64,091–7,706,113, 144 genes (broad region; genes not listed).
- chr8:11,421,476–12,177,550, 32 genes (within-gene range 0–2): FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:21,638,285–22,455,740, 19 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr12:76,660,405–76,853,696, 4 genes: AC107032.1, RPL7P43, AC093014.1, ZDHHC17.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–5): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–5): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–5): IGHV3-43.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 399 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,020,120–2,817,767, 107 genes, copy number 9 (broad region; genes not listed).
- chr2:38,814–209,892, 2 genes, copy number 11: FAM110C, AC079779.1.
- chr2:8,600,892–9,405,683, 14 genes, copy number 9 (within-gene range 6–9): AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7.
- chr6:6,144,084–7,389,742, 27 genes, copy number 10 (within-gene range 8–10): F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3.
- chr6:7,620,422–8,102,559, 9 genes, copy number 10: AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1.
- chr6:8,158,162–8,760,447, 1 gene, copy number 11 (within-gene range 2–11): AL355499.2.
- chr6:8,411,435–8,435,561, 1 gene, copy number 11: SLC35B3.
- chr6:9,596,110–10,634,695, 19 genes, copy number 10–13: OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1.
- chr11:66,638,667–67,072,017, 16 genes, copy number 9 (within-gene range 6–9): RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD.
- chr11:72,836,745–73,181,724, 4 genes, copy number 9 (within-gene range 6–9): FCHSD2, RNU6-672P, AP002381.1, AP002761.2.
- chr11:73,264,505–73,298,625, 1 gene, copy number 9: P2RY6.
- chr11:73,400,487–73,598,189, 1 gene, copy number 12 (within-gene range 8–12): FAM168A.
- chr11:73,452,020–78,418,348, 157 genes, copy number 9–16 (within-gene range 7–16) (broad region; genes not listed).
- chr11:78,435,968–79,441,030, 10 genes, copy number 9 (within-gene range 7–12): NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579.
- chr11:79,966,805–80,327,911, 3 genes, copy number 10: AP001541.1, AP001284.1, AP006295.1.
- chr17:56,573,040–56,595,611, 2 genes, copy number 9: RPL39P33, NOG.
- chr17:70,628,917–70,779,230, 2 genes, copy number 10–11: AC005771.1, AC007423.1.
- chr17:73,163,035–73,828,520, 17 genes, copy number 9 (within-gene range 4–9): POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092.
- chr17:77,959,240–78,142,968, 6 genes, copy number 10: TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8.

Autosomal genes at a single copy (total copy number 1): 1,448. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
